Somatic mutation profile of tumor specimen TCGA-A2-A0EM-01A (aliquot TCGA-A2-A0EM-01A-11W-A050-09) from TCGA case TCGA-A2-A0EM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.5 years (26,845 days).
Specimen TCGA-A2-A0EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8ed13a0-2630-4773-9716-c81cbcafd34f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0EM-10A (Blood Derived Normal), aliquot TCGA-A2-A0EM-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f44f18b-a754-49e2-8ed0-1905d323d480

The open-access MAF lists 28 somatic variants for this specimen: 26 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Nonsense Mutation 2, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 59/161 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BOD1L1 | c.5909C>T p.P1970L | Missense Mutation (SNP) | VAF 13/399 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV50155098; called by muse, mutect2
- CCDC105 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.2); catalogued as COSV52963447; called by muse, mutect2, varscan2
- COL27A1 | c.2851A>T p.M951L | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV61923071; called by muse, mutect2, varscan2
- CPN1 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV64942060; called by muse, mutect2, varscan2
- FGF11 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs370094891; called by muse, mutect2, varscan2
- GPR143 | c.488G>A p.G163D | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as CM034735, COSV66632080; called by muse, mutect2, varscan2
- GSDMB | c.766G>A p.E256K (on ENST00000418519 / NM_001165958.1; = p.E234K on NM_018530.2) | Missense Mutation (SNP) | VAF 11/340 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as COSV100522844; called by muse, mutect2
- HRH2 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV51573366; called by muse, mutect2, varscan2
- MAGEL2 | c.2725C>T p.Q909* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV58566316; called by muse, mutect2, varscan2
- MYEF2 | c.1608G>A p.W536* | Nonsense Mutation (SNP) | VAF 181/521 reads (35%) | catalogued as COSV51046535; called by muse, mutect2, varscan2
- MYO7A | c.4850C>A p.P1617H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV68683939; called by muse, mutect2, varscan2
- NOS1AP | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as COSV62632980; called by muse, mutect2, varscan2
- PCDHA11 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.56); catalogued as rs1554162716, COSV56485082; called by muse, mutect2, varscan2
- PLCB4 | c.2164G>A p.V722I | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs772944610, COSV53796321, COSV99059197; called by muse, mutect2, varscan2
- PPP1R13B | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); catalogued as COSV52449730; called by muse, mutect2, varscan2
- RCOR1 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 254/764 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51766552; called by muse, mutect2, varscan2
- RNF103 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 18/573 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99410284; called by muse, mutect2
- SAMSN1 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53470359, COSV99581996; called by muse, mutect2
- SGCZ | c.60del p.L21* | Frame Shift Del (DEL) | VAF 256/856 reads (30%) | catalogued as COSV66002621; called by mutect2, pindel, varscan2
- SMYD3 | c.1217G>A p.R406K (on ENST00000490107 / NM_001375962.1; = p.R347K on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/517 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.038); catalogued as COSV63626042; called by muse, mutect2, varscan2
- TPP1 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54993687; called by muse, mutect2, varscan2
- ZMAT5 | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV60242972; called by muse, mutect2, varscan2
- ZNF70 | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 169/498 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV59532372; called by muse, mutect2, varscan2
- FAM13C | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 16/369 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by muse, mutect2
- KMT2C | c.7307dup p.P2437Tfs*8 | Frame Shift Ins (INS) | VAF 125/389 reads (32%) | called by mutect2, pindel, varscan2
- PAK3 | c.1587G>A p.L529= (on ENST00000262836 / NM_001324328.2; = p.L514= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 34/560 reads (6%) | catalogued as COSV99457905; called by muse, mutect2
- XIRP2 | c.*1523A>T | 3'UTR (SNP) | VAF 37/81 reads (46%) | catalogued as COSV54688399; called by muse, mutect2, varscan2
